MMRF case MMRF_1643 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ba8c9c1a-9c21-49ae-bfa9-eab77f2d6384

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.4 years (22,787 days); ISS stage: I; Days to last known disease status: 1,219 days (3.3 years); Days to last follow up: 1,219 days (3.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,219.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 0): M Protein 2.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 35.4 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 2.18 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 9 g/dL; Glucose 5.61 mmol/L; C-Reactive Protein 0.12 mg/dL.
- Day 106: M Protein 0.6 g/dL; Hemoglobin 8.68 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 6.38 mmol/L.
- Day 162: M Protein 0.3 g/dL; Hemoglobin 8.99 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 7.43 mmol/L.
- Day 311 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.852 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.604 mg/dL; Immunoglobulin G 5.86 g/L; Immunoglobulin A 0.88 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6 mmol/L.
- Day 421: M Protein 0 g/dL; Immunoglobulin G 6.74 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.6 g/L; Hemoglobin 9.61 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 5.61 mmol/L.
- Day 536: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 9.73 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 9.18 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.62 mmol/L.
- Day 625 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 2.04 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 9.8 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 6.05 mmol/L.
- Day 717 (ECOG 0): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.991 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 1.39 µg/mL; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 8.91 mmol/L.
- Day 795: Hemoglobin 8.99 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 123 ×10⁹/L.
- Day 886: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 7.45 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.47 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 5.72 mmol/L.
- Day 949: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 7.48 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 6.33 mmol/L.
- Day 1,020: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 6.85 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.38 g/L.

Other clinical attributes
- Day -19: Weight: 85 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1643_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_1643_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
